Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5104, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5104-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, RADICAL LAPAROSCOPIC NEPHRECTOMY -

A. RENAL CELL CARCINOMA, CLEAR CELL TYPE, 4.5 CM IN DIAMETER.

B. TUMOR IS CONFINED TO THE KIDNEY PARENCHYMA.

C. NO ANGIOLYMPHATIC INVASION SEEN.

D. NON-NEOPLASTIC RENAL PARENCHYMA WITH FOCAL CHRONIC INFLAMMATION AND FOCAL GLOMERULOSCLEROSIS.

E. SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASM.

F. TNM STAGE: T1NXMX.

G. HISTOPATHOLOGICAL GRADE: G2.

Source: NCI Genomic Data Commons file a37bc310-0fb5-46e2-8311-6dc05745dc81 (TCGA-B0-5104.B8335D43-8B5E-4D00-974F-C37642AA0D7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).